Somatic mutation profile of tumor specimen MP2PRT-PARSZU-TMP1-A (aliquot MP2PRT-PARSZU-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PARSZU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,475 days).
Specimen MP2PRT-PARSZU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cab8e9cf-7f6d-4ebc-a956-0c062d0fd3d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARSZU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARSZU-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5a211a3-1b13-408f-8864-22489c0a8449

The open-access MAF lists 20 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 5, Frame Shift Del 1, Nonsense Mutation 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DMD | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 85/428 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as rs772546251, COSV55899047; called by muse, mutect2, varscan2
- FAP | c.1477G>C p.E493Q | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV51861399; called by muse, mutect2, varscan2
- LGR6 | c.1022G>A p.R341Q (on ENST00000367278 / NM_001017403.1; = p.R289Q on NM_021636.3) | Missense Mutation (SNP) | VAF 88/409 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs777727797; called by muse, mutect2, varscan2
- NOTCH3 | c.3647C>T p.A1216V | Missense Mutation (SNP) | VAF 69/684 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1265324934; called by muse, mutect2, varscan2
- PDE6B | c.2215G>A p.E739K | Missense Mutation (SNP) | VAF 78/404 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs778255348; called by muse, mutect2, varscan2
- PGBD5 | c.346G>A p.V116I (on ENST00000525115; = p.V185I on NM_001258311.2) | Missense Mutation (SNP) | VAF 159/580 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.4); catalogued as rs564271297, COSV58412071; called by muse, mutect2, varscan2
- TTN | c.5947G>A p.E1983K (on ENST00000591111; = p.E1937K on NM_003319.4) | Missense Mutation (SNP) | VAF 27/560 reads (5%) | PolyPhen possibly damaging (0.73); catalogued as COSV60338473; called by muse, mutect2
- ADAMTS19 | c.641C>G p.S214C | Missense Mutation (SNP) | VAF 95/763 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- GABRG1 | c.1062G>T p.L354F | Missense Mutation (SNP) | VAF 53/286 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HOXA6 | c.666_680delinsTGGGG p.S223Gfs*? | Frame Shift Del (DEL) | VAF 149/538 reads (28%) | called by pindel, varscan2*
- NPEPPS | c.172_173insA p.V58Dfs*34 | Frame Shift Ins (INS) | VAF 132/717 reads (18%) | called by mutect2, pindel, varscan2
- NR2F2 | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 88/857 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- TAF1L | c.1945C>T p.Q649* | Nonsense Mutation (SNP) | VAF 154/778 reads (20%) | called by muse, mutect2, varscan2
- THSD4 | c.1367G>T p.S456I | Missense Mutation (SNP) | VAF 122/346 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ABCA1 | c.2319C>T p.F773= | Silent (SNP) | VAF 76/333 reads (23%) | called by muse, mutect2, varscan2
- COL6A1 | c.2499G>A p.L833= | Silent (SNP) | VAF 36/607 reads (6%) | called by muse, mutect2
- PCDHA12 | c.1833G>A p.L611= | Silent (SNP) | VAF 249/606 reads (41%) | called by muse, mutect2, varscan2
- TMEM140 | c.468C>T p.S156= | Silent (SNP) | VAF 38/576 reads (7%) | catalogued as rs764481357; called by muse, mutect2
- UBR2 | c.1500C>T p.F500= | Silent (SNP) | VAF 72/392 reads (18%) | called by muse, mutect2, varscan2
- AL353804.6 | chrX:73827227 C>G | 3'Flank (SNP) | VAF 34/453 reads (8%) | called by muse, mutect2
